Somatic mutation profile of tumor specimen MP2PRT-PAVRXY-TMP1-A (aliquot MP2PRT-PAVRXY-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVRXY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.3 years (1,932 days).
Specimen MP2PRT-PAVRXY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 776d3422-39f8-4507-8b2f-2ab72523b344.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVRXY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVRXY-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a0c8360-8a90-47e1-8540-443ce1bbd6d3

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, Nonsense Mutation 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 52/340 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKFY1 | c.2576G>A p.R859Q (on ENST00000341657 / NM_001330063.2; = p.R860Q on NM_016376.5) | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs765652697; called by muse, mutect2, varscan2
- IL13RA2 | c.973T>C p.W325R | Missense Mutation (SNP) | VAF 24/386 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1556508000; called by muse, mutect2
- KRTAP9-4 | c.331G>C p.V111L | Missense Mutation (SNP) | VAF 245/741 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1300393080; called by muse, mutect2, varscan2
- MIPOL1 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs778762357; called by muse, mutect2
- PAPPA2 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 18/488 reads (4%) | catalogued as COSV62774852; called by muse, mutect2
- SMG8 | c.2557G>C p.D853H | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV99958696; called by muse, mutect2
- TEK | c.140C>G p.S47C | Missense Mutation (SNP) | VAF 156/364 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs998969484; called by muse, mutect2, varscan2
- ATP7B | c.316G>T p.V106F | Missense Mutation (SNP) | VAF 56/341 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- BOD1L1 | c.3517G>A p.D1173N | Missense Mutation (SNP) | VAF 157/399 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- NOL7 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 127/314 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- RINL | c.431_432insCCCCGG p.G144_P145dup (on ENST00000591812 / NM_001195833.2; = p.G30_P31dup on NM_198445.4) | In Frame Ins (INS) | VAF 100/284 reads (35%) | called by mutect2, varscan2
- RNF38 | c.986C>G p.S329* | Nonsense Mutation (SNP) | VAF 171/434 reads (39%) | called by muse, mutect2, varscan2
- STOX2 | c.2124C>G p.H708Q | Missense Mutation (SNP) | VAF 161/360 reads (45%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF735 | c.1157G>A p.C386Y | Missense Mutation (SNP) | VAF 81/249 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF804A | c.2766T>G p.S922R | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- IGKV1D-43 | c.351T>C p.P117= | Silent (SNP) | VAF 54/135 reads (40%) | catalogued as rs560413135; called by muse, mutect2, varscan2
- KAT14 | c.2253C>T p.F751= | Silent (SNP) | VAF 29/454 reads (6%) | catalogued as COSV66606500; called by muse, mutect2
- NEUROD6 | c.975C>T p.L325= | Silent (SNP) | VAF 129/378 reads (34%) | catalogued as rs749044741; called by muse, mutect2, varscan2
- PDE3A | c.2508C>T p.H836= | Silent (SNP) | VAF 139/332 reads (42%) | catalogued as rs923392546, COSV100761609, COSV62979973; called by muse, mutect2, varscan2
